Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A95V, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A95V-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-O-3

Melanoma NOS 8720/3
Site: Lymph nodes of head
face & neck C77.0
JWS 5/16/14

Criteria	JWS 12/23/13	Yes	No

Specimen(s) Received:
RIGHT NECK NODES

FINAL DIAGNOSIS

LYMPH NODES AND SUBMANDIBULAR GLAND, RIGHT NECK, EXCISION:

- METASTATIC MELANOMA (2.5 CM)
INVOLVING ONE OF TWO LYMPH NODES (1/2)
- SUBMANDIBULAR GLAND WITHOUT SIGNIFICANT ABNORMALITY

Pathologist:

*** Report Electronically Signed Out ***

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

Received fresh labeled with the patient's name and "right neck nodes" is a 4.0 x 3.2 x 1.8 cm irregular portion of hemorrhagic adipose tissue. The specimen contains a 2.5 cm in greatest dimension pigmented, grossly positive lymph node from which a portion of tissue was previously taken for research (inked orange by researcher). Also identified is a 3.2 cm in greatest dimension portion of lobulated fibrotic soft tissue. Also identified is a 1.0 cm in greatest dimension pink-red, rubbery lymph node. Representative sections are submitted in 5 cassettes as follows: Cassette 1-representative section of largest grossly positive node, cassettes 2-4-lobulated soft tissue, cassette 5-smallest bisected lymph node. (

Summary of Tissue Submitted for Microscopic Examination

Block Detail

Part 1] RIGHT NECK NODES

# Blocks	Designation	#	Description
5	[Undes]	(5)	(No Description)

[page 2 of 2]
[REDACTED]

[REDACTED]

Printed by:

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 4af6b340-38d9-4d1d-9080-2a1c74bd8afa (TCGA-DA-A95V.0BCAC5F8-C578-4AF2-96AD-E632A5D92470.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).